Somatic mutation profile of tumor specimen TCGA-AC-A5EH-01A (aliquot TCGA-AC-A5EH-01A-11D-A28B-09) from TCGA case TCGA-AC-A5EH, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 76.6 years (27,964 days).
Specimen TCGA-AC-A5EH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dc08e557-cfbc-42a0-aba1-fdc7694bf361.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AC-A5EH-10A (Blood Derived Normal), aliquot TCGA-AC-A5EH-10A-01D-A28E-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fbbecbfe-acb3-40c3-8f55-b62ec79f3024

The open-access MAF lists 154 somatic variants for this specimen: 112 protein-altering or splice-affecting, 37 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 91, Silent 37, Nonsense Mutation 9, Splice Site 5, Frame Shift Ins 2, Intron 2, Splice Region 2, Nonstop Mutation 1, 3'UTR 1, In Frame Del 1, 3'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.3870+1G>T p.X1290_splice | Splice Site (SNP) | VAF 7/28 reads (25%) | catalogued as rs1131691075, CS011840, CS012213, CS072250, COSV62214118, COSV62218158; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 8/25 reads (32%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.581T>G p.L194R | Missense Mutation (SNP) | VAF 20/43 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519998, COSV52663681, COSV52677924, COSV52679257, COSV52713187; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ABCB8 | c.1100G>A p.R367Q (on ENST00000297504 / NM_001282291.2; = p.R350Q on NM_007188.5) | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs374885136; called by muse, mutect2, varscan2
- ABCC1 | c.1658G>A p.W553* | Nonsense Mutation (SNP) | VAF 8/26 reads (31%) | catalogued as COSV100578652; called by muse, mutect2, varscan2
- ABCC9 | c.2799G>C p.E933D | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.077); catalogued as COSV53972501, COSV99684647; called by muse, mutect2, varscan2
- ABHD17C | c.649A>G p.T217A | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.344); catalogued as COSV99358519; called by muse, mutect2, varscan2
- ADGRE3 | c.1634A>G p.Q545R | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.06); catalogued as COSV99505864; called by muse, mutect2, varscan2
- ADORA2A | c.43G>T p.A15S | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.077); catalogued as COSV100417843; called by muse, mutect2, varscan2
- ALDH1L1 | c.2185G>A p.E729K | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.022); catalogued as COSV99856536; called by muse, mutect2, varscan2
- AMZ1 | c.149C>T p.P50L | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs200667897, COSV56686806; called by muse, mutect2, varscan2
- ANGPT4 | c.309+2T>C p.X103_splice | Splice Site (SNP) | VAF 21/80 reads (26%) | catalogued as COSV101124646; called by muse, mutect2, varscan2
- ARHGAP30 | c.215C>T p.S72L | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.026); catalogued as COSV100920143; called by muse, mutect2, varscan2
- ATP6V0B | c.115T>C p.W39R | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV99356261; called by muse, mutect2
- BBOX1 | c.80C>A p.S27Y | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99589459; called by muse, mutect2, varscan2
- BOC | c.2881C>T p.Q961* | Nonsense Mutation (SNP) | VAF 13/82 reads (16%) | catalogued as COSV99848181; called by muse, mutect2, varscan2
- BRINP1 | c.995G>T p.W332L | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV99774521; called by muse, mutect2, varscan2
- BSN | c.1010G>C p.G337A | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.257); catalogued as COSV99607394; called by muse, mutect2, varscan2
- CACTIN | c.645C>A p.A215= | Splice Region (SNP) | VAF 7/30 reads (23%) | catalogued as COSV50272620, COSV50274075; called by muse, mutect2, varscan2
- CCIN | c.936C>A p.D312E | Missense Mutation (SNP) | VAF 28/50 reads (56%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100631723; called by muse, mutect2, varscan2
- CDH6 | c.506C>T p.P169L | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99418178; called by muse, mutect2
- CTTNBP2 | c.4081G>A p.V1361I | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.01); catalogued as rs781254525, COSV50495435; called by muse, mutect2, varscan2
- DLGAP1 | c.268C>T p.R90C | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.298); catalogued as COSV59839762; called by muse, mutect2, varscan2
- DUSP22 | c.272G>C p.G91A | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100739664, COSV99078015; called by muse, mutect2, varscan2
- ENTHD1 | c.1247C>A p.S416Y | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV100288470; called by muse, mutect2, varscan2
- F11R | c.593T>A p.V198D | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.443); catalogued as COSV57035630, COSV99230794; called by muse, mutect2, varscan2
- F8 | c.6658G>A p.A2220T | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.087); catalogued as CM002005, COSV100371496; called by muse, mutect2, varscan2
- FAM71D | c.467C>G p.S156C | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as COSV100315117; called by muse, mutect2, varscan2
- FRMD8 | c.955G>C p.E319Q | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100454589; called by muse, mutect2, varscan2
- GDPD4 | c.638A>G p.N213S | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100265064; called by muse, mutect2, varscan2
- HAUS5 | c.962G>C p.R321P | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.774); catalogued as COSV99177870; called by muse, mutect2, varscan2
- HIF3A | c.1772C>G p.P591R (on ENST00000377670 / NM_152795.4; = p.P522R on NM_022462.4) | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV99355551; called by muse, mutect2, varscan2
- HNRNPUL1 | c.1352A>C p.N451T | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.16); catalogued as COSV99646937; called by muse, mutect2, varscan2
- HSD17B4 | c.1919C>G p.T640R (on ENST00000414835 / NM_001199291.3; = p.T615R on NM_000414.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0.006); catalogued as COSV99819547; called by muse, mutect2, varscan2
- HSF5 | c.1616T>A p.I539N | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); catalogued as COSV100089861; called by muse, mutect2, varscan2
- IFITM5 | c.29C>T p.T10I | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs1252941483, COSV101164302; called by muse, mutect2, varscan2
- KBTBD7 | c.1367G>T p.C456F | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV101068026; called by muse, mutect2, varscan2
- KCNU1 | c.3272C>A p.S1091Y | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.076); catalogued as COSV67759597; called by muse, mutect2, varscan2
- KIAA1109 | c.7532C>T p.P2511L | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99145979; called by muse, mutect2, varscan2
- KIAA1210 | c.3807A>C p.E1269D | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.948); catalogued as COSV101273931; called by muse, mutect2, varscan2
- KIF15 | c.407T>A p.I136N | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100392531; called by muse, mutect2, varscan2
- KMO | c.947G>A p.G316E | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100844668; called by muse, mutect2, varscan2
- KMT2C | c.13171A>T p.K4391* | Nonsense Mutation (SNP) | VAF 7/17 reads (41%) | catalogued as COSV100067706; called by muse, mutect2, varscan2
- LAMA2 | c.7412G>T p.G2471V | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101370126; called by muse, mutect2, varscan2
- LRP2 | c.10687G>A p.G3563S | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs745375377, COSV55576099; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MARK3 | c.718G>C p.G240R | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99357852; called by muse, mutect2
- MASP1 | c.1484C>T p.S495L | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV61828042; called by muse, mutect2, varscan2
- MED16 | c.1717G>T p.D573Y | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99515169; called by muse, mutect2, varscan2
- MORC1 | c.2224C>T p.Q742* | Nonsense Mutation (SNP) | VAF 21/98 reads (21%) | catalogued as COSV99225200; called by muse, mutect2, varscan2
- MSH5 | c.766+1G>T p.X256_splice | Splice Site (SNP) | VAF 8/30 reads (27%) | catalogued as COSV100994708; called by muse, mutect2, varscan2
- MST1R | c.4083G>T p.M1361I | Missense Mutation (SNP) | VAF 31/108 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.009); catalogued as COSV99617840, COSV99619920; called by muse, mutect2, varscan2
- MYH10 | c.5298G>A p.V1766= | Splice Region (SNP) | VAF 10/39 reads (26%) | catalogued as COSV99344207; called by muse, mutect2, varscan2
- MYO16 | c.598A>G p.S200G | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.266); catalogued as COSV99193564; called by muse, mutect2, varscan2
- MYO5B | c.559G>A p.A187T | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV99543743; called by muse, mutect2, varscan2
- NCAPD2 | c.1692T>A p.N564K | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.034); catalogued as COSV100216895; called by muse, varscan2
- NCKAP1 | c.2330A>G p.D777G | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100720014; called by muse, mutect2
- NIN | c.517C>A p.Q173K | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as COSV99811856; called by muse, mutect2
- NLRP9 | c.1320T>A p.C440* | Nonsense Mutation (SNP) | VAF 10/34 reads (29%) | catalogued as COSV100242643; called by muse, mutect2, varscan2
- NTRK3 | c.1106C>A p.T369N | Missense Mutation (SNP) | VAF 40/138 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100445576; called by muse, mutect2, varscan2
- NUP54 | c.1392G>T p.K464N | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.567); catalogued as COSV99345161; called by muse, mutect2, varscan2
- OR2T1 | c.955T>G p.*319Gext*47 | Nonstop Mutation (SNP) | VAF 13/42 reads (31%) | catalogued as COSV100822255; called by muse, mutect2, varscan2
- OR4D6 | c.646G>C p.G216R | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.601); catalogued as COSV100271575; called by muse, mutect2
- OR5AU1 | c.320T>G p.F107C | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.059); catalogued as COSV100436072; called by muse, mutect2, varscan2
- OR7D2 | c.430C>G p.L144V | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as COSV100712950, COSV60140350; called by muse, mutect2, varscan2
- OTOGL | c.3505C>G p.L1169V (on ENST00000547103; = p.L1160V on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.924); catalogued as COSV101509027, COSV72007010; called by muse, mutect2, varscan2
- PARP9 | c.914C>A p.T305N | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.598); catalogued as COSV100830946; called by muse, mutect2, varscan2
- PCDHB2 | c.1252G>A p.E418K | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.192); catalogued as rs782217826, COSV99164208; called by muse, mutect2, varscan2
- PEAK1 | c.1915G>C p.A639P | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100432492; called by muse, mutect2, varscan2
- PICALM | c.274-1G>A p.X92_splice | Splice Site (SNP) | VAF 3/18 reads (17%) | catalogued as COSV100707721; called by muse, mutect2
- PKD1 | c.1807G>T p.A603S | Missense Mutation (SNP) | VAF 34/129 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.101); catalogued as rs762060197, COSV99237246; called by muse, mutect2, varscan2
- PPFIA2 | c.2533C>T p.R845* | Nonsense Mutation (SNP) | VAF 8/23 reads (35%) | catalogued as COSV61030722; called by muse, mutect2, varscan2
- PSMA8 | c.51C>A p.H17Q | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.254); catalogued as COSV100378651, COSV100378781; called by muse, mutect2, varscan2
- PYGL | c.278G>A p.G93D | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99368285; called by muse, mutect2
- RAB11FIP2 | c.19G>C p.A7P | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.445); catalogued as rs778880042, COSV100842997; called by muse, mutect2, varscan2
- RNF213 | c.8727G>T p.E2909D | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV100299785; called by muse, mutect2, varscan2
- ROBO1 | c.3740C>T p.A1247V | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.074); catalogued as COSV101458332; called by muse, mutect2, varscan2
- RPL10 | c.208A>C p.I70L | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.266); catalogued as COSV50010499; called by muse, mutect2, varscan2
- RSAD1 | c.535C>T p.R179W | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.625); catalogued as rs373296180, COSV51955978; called by muse, mutect2, varscan2
- SFXN1 | c.785G>T p.W262L | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV100369192; called by muse, mutect2, varscan2
- SH3RF1 | c.2125G>C p.D709H | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99498687, COSV99499297; called by muse, mutect2, varscan2
- SHISA5 | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (0.99); PolyPhen benign (0.003); catalogued as rs375027466; called by muse, mutect2, varscan2
- SIPA1L1 | c.1342G>C p.E448Q | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.373); catalogued as rs371174898; called by muse, mutect2, varscan2
- SLC44A1 | c.136T>C p.C46R | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV101029089; called by muse, mutect2, varscan2
- SLC49A3 | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as COSV100448353; called by muse, mutect2
- SLC9A3R2 | c.334C>A p.L112I | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV70166022; called by muse, mutect2
- SLCO1C1 | c.1176C>A p.N392K | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.958); catalogued as COSV99858569; called by muse, mutect2, varscan2
- STRC | c.5117C>T p.S1706F | Missense Mutation (SNP) | VAF 29/137 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as COSV100294444, COSV55853015; called by muse, mutect2, varscan2
- SYNE1 | c.8200C>G p.Q2734E (on ENST00000367255 / NM_182961.4; = p.Q2741E on NM_033071.3) | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.16); catalogued as COSV54904437, COSV99554752; called by muse, mutect2, varscan2
- TAFA4 | c.316C>T p.H106Y | Missense Mutation (SNP) | VAF 32/69 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV99806414; called by muse, mutect2, varscan2
- TFCP2L1 | c.974A>G p.Q325R | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as COSV99747800; called by muse, mutect2, varscan2
- TJP1 | c.1921+1G>A p.X641_splice | Splice Site (SNP) | VAF 6/22 reads (27%) | catalogued as COSV100632365; called by muse, mutect2, varscan2
- TLR9 | c.373C>G p.L125V | Missense Mutation (SNP) | VAF 44/160 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV100564450; called by muse, mutect2, varscan2
- TMC8 | c.1897G>C p.V633L | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV100573681; called by muse, mutect2
- TNFRSF8 | c.1721A>T p.D574V | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as COSV99821138; called by muse, mutect2, varscan2
- TSPEAR | c.529C>T p.L177F | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.372); catalogued as rs763983735, COSV100552071; called by muse, mutect2, varscan2
- TTK | c.1822G>C p.D608H | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57881234, COSV57884279; called by muse, mutect2, varscan2
- UNC13A | c.536A>C p.Y179S | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.969); catalogued as COSV99407279; called by muse, mutect2, varscan2
- VIT | c.464C>A p.S155* | Nonsense Mutation (SNP) | VAF 12/43 reads (28%) | catalogued as COSV101007174, COSV64895180; called by muse, mutect2, varscan2
- VRTN | c.1610C>A p.S537* | Nonsense Mutation (SNP) | VAF 20/100 reads (20%) | catalogued as COSV99832129; called by muse, mutect2, varscan2
- WDR24 | c.1214A>T p.D405V (on ENST00000248142; = p.D275V on NM_032259.4) | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99555415; called by muse, mutect2, varscan2
- WFIKKN2 | c.1346A>T p.K449M | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV100259736, COSV60958467; called by muse, mutect2, varscan2
- ZNF208 | c.1023C>A p.Y341* | Nonsense Mutation (SNP) | VAF 16/29 reads (55%) | catalogued as COSV101236866; called by muse, mutect2, varscan2
- ZNF394 | c.821G>T p.G274V | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.55); PolyPhen benign (0.005); catalogued as COSV100529811; called by muse, mutect2, varscan2
- ZNRF4 | c.1151G>C p.W384S | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV99706360, COSV99706432; called by muse, mutect2, varscan2
- C12orf45 | c.137_139del p.I46del | In Frame Del (DEL) | VAF 16/66 reads (24%) | called by pindel, varscan2
- CALR3 | c.880_887del p.F294Hfs*18 | Frame Shift Del (DEL) | VAF 13/33 reads (39%) | called by mutect2, pindel, varscan2
- IGHV3-74 | c.179C>T p.P60L | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.328); called by muse, mutect2, varscan2
- MRC1 | c.2174G>T p.G725V | Missense Mutation (SNP) | VAF 26/193 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLG | c.1359dup p.C454Mfs*59 | Frame Shift Ins (INS) | VAF 8/61 reads (13%) | called by mutect2, pindel, varscan2
- SPATA31A3 | c.3251T>G p.V1084G | Missense Mutation (SNP) | VAF 64/115 reads (56%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- SRCAP | c.409dup p.W137Lfs*14 | Frame Shift Ins (INS) | VAF 21/86 reads (24%) | called by mutect2, pindel, varscan2
- TRAV41 | c.292G>T p.A98S | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.92); PolyPhen possibly damaging (0.525); called by muse, mutect2, varscan2
- ADCY2 | c.1299G>A p.E433= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as rs777389360, COSV100601886; called by mutect2, varscan2
- ASMT | c.27T>C p.Y9= | Silent (SNP) | VAF 7/71 reads (10%) | catalogued as COSV101172415; called by muse, mutect2
- BMPR2 | c.2703T>C p.N901= | Silent (SNP) | VAF 10/56 reads (18%) | catalogued as COSV101001276; called by muse, mutect2, varscan2
- BRCA1 | c.4449T>C p.S1483= | Silent (SNP) | VAF 17/36 reads (47%) | catalogued as COSV100523372; called by muse, mutect2, varscan2
- CCDC146 | c.24A>G p.T8= | Silent (SNP) | VAF 21/112 reads (19%) | catalogued as COSV99592205; called by muse, mutect2, varscan2
- CD244 | c.30C>A p.L10= | Silent (SNP) | VAF 13/68 reads (19%) | catalogued as COSV100458264; called by muse, mutect2, varscan2
- CECR2 | c.231A>G p.T77= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as COSV99377111; called by muse, mutect2, varscan2
- CHD5 | c.5847C>G p.P1949= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as COSV99312597; called by muse, mutect2, varscan2
- CHFR | c.627G>C p.G209= (on ENST00000432561 / NM_001161345.1; = p.G168= on NM_018223.2) | Silent (SNP) | VAF 18/56 reads (32%) | catalogued as COSV57176681, COSV99904996; called by muse, mutect2, varscan2
- CLCN4 | c.1044C>G p.L348= | Silent (SNP) | VAF 9/60 reads (15%) | catalogued as COSV101073671, COSV66468147; called by muse, mutect2, varscan2
- COL1A1 | c.1554C>T p.G518= | Silent (SNP) | VAF 27/46 reads (59%) | catalogued as COSV99866473; called by muse, mutect2, varscan2
- COL2A1 | c.4452C>A p.V1484= | Silent (SNP) | VAF 12/97 reads (12%) | catalogued as CD050438, COSV99873351; called by muse, mutect2, varscan2
- COL6A5 | c.7440C>A p.I2480= (on ENST00000312481; = p.I2476= on NM_153264.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as COSV99592033; called by muse, mutect2, varscan2
- CREBBP | c.435C>A p.P145= | Silent (SNP) | VAF 19/46 reads (41%) | catalogued as COSV99268709; called by muse, mutect2, varscan2
- CREBZF | c.456G>C p.A152= | Silent (SNP) | VAF 5/47 reads (11%) | catalogued as COSV99476121; called by muse, mutect2, varscan2
- DUSP16 | c.345C>T p.F115= | Silent (SNP) | VAF 14/32 reads (44%) | catalogued as COSV99962956; called by muse, mutect2, varscan2
- FRMPD1 | c.1530C>T p.H510= | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as rs765831714, COSV100899342; called by muse, mutect2, varscan2
- GDPD5 | c.864G>A p.E288= | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as rs143749567; called by muse, mutect2, varscan2
- GIMAP2 | c.795C>A p.A265= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as COSV99785222; called by muse, mutect2, varscan2
- IFT122 | c.3243C>T p.F1081= (on ENST00000348417 / NM_052989.3; = p.F1022= on NM_018262.4) | Silent (SNP) | VAF 24/78 reads (31%) | catalogued as rs746196323, COSV56201908, COSV99958788; called by muse, mutect2, varscan2
- KIN | c.657T>G p.S219= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as COSV101092430; called by muse, mutect2, varscan2
- KMT2C | c.57C>G p.P19= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as rs548005028, COSV100067709, COSV51402237; called by muse, mutect2, varscan2
- MACO1 | c.276G>C p.L92= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as COSV100975032; called by muse, mutect2, varscan2
- PABPC1L | c.609C>T p.D203= | Silent (SNP) | VAF 5/70 reads (7%) | catalogued as rs1227408363, COSV99407525; called by muse, mutect2
- PCDHA5 | c.1839G>A p.A613= | Silent (SNP) | VAF 44/158 reads (28%) | catalogued as rs569811082, COSV100972127; called by muse, mutect2, varscan2
- PNLIP | c.816T>A p.T272= | Silent (SNP) | VAF 4/56 reads (7%) | catalogued as COSV100981639, COSV100981813; called by muse, mutect2
- POP1 | c.2019G>A p.A673= | Silent (SNP) | VAF 21/48 reads (44%) | catalogued as rs750752565, COSV100855644, COSV100856118; called by muse, mutect2, varscan2
- RAG1 | c.2367G>A p.E789= | Silent (SNP) | VAF 13/37 reads (35%) | catalogued as COSV100200678; called by muse, mutect2, varscan2
- SEC24C | c.1350C>T p.C450= | Silent (SNP) | VAF 13/85 reads (15%) | catalogued as COSV100226545; called by muse, mutect2, varscan2
- SEZ6L2 | c.1311C>G p.L437= (on ENST00000308713 / NM_001114099.3; = p.L367= on NM_012410.4) | Silent (SNP) | VAF 16/42 reads (38%) | catalogued as COSV100435130; called by muse, mutect2, varscan2
- SLC12A5 | c.2532C>T p.F844= (on ENST00000454036 / NM_001134771.2; = p.F821= on NM_020708.5) | Silent (SNP) | VAF 23/106 reads (22%) | catalogued as COSV99715416; called by muse, mutect2, varscan2
- TGM7 | c.810C>T p.G270= | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as rs758729719, COSV101476823; called by muse, mutect2, varscan2
- TMEM163 | c.546C>T p.L182= | Silent (SNP) | VAF 14/57 reads (25%) | catalogued as rs768273755, COSV99925735; called by muse, mutect2, varscan2
- TNC | c.5562G>C p.L1854= | Silent (SNP) | VAF 28/66 reads (42%) | catalogued as COSV100405065; called by muse, mutect2, varscan2
- TRIOBP | c.5406C>G p.T1802= (on ENST00000644935 / NM_001039141.3; = p.T89= on NM_007032.5) | Silent (SNP) | VAF 15/77 reads (19%) | catalogued as rs753830322, COSV100462240; called by muse, mutect2, varscan2
- TRPT1 | c.477G>A p.L159= (on ENST00000317459 / NM_001160393.1; = p.L110= on NM_031472.4) | Silent (SNP) | VAF 4/45 reads (9%) | catalogued as COSV99655674; called by muse, mutect2
- TTBK2 | c.2757T>C p.C919= | Silent (SNP) | VAF 11/26 reads (42%) | catalogued as rs552522869, COSV99141110; called by muse, mutect2, varscan2
- AC092718.9 | chr16:81154269 C>G | 3'Flank (SNP) | VAF 17/36 reads (47%) | catalogued as rs763972939; called by muse, mutect2, varscan2
- CCNB1IP1 | c.-153+242A>T | Intron (SNP) | VAF 5/41 reads (12%) | catalogued as COSV100738506; called by muse, mutect2
- GPR42 | c.-2C>A | 5'UTR (SNP) | VAF 10/38 reads (26%) | called by muse, mutect2, varscan2
- HAUS7 | c.961-453T>A | Intron (SNP) | VAF 11/46 reads (24%) | catalogued as COSV100444002; called by muse, mutect2, varscan2
- XIRP2 | c.*623A>T | 3'UTR (SNP) | VAF 5/29 reads (17%) | catalogued as COSV99738904; called by muse, mutect2
